Somatic mutation profile of tumor specimen 0DWD2D from CCDI case PBCPCC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 0.8 years (308 days).
Specimen 0DWD2D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15a3ef04-8940-4ca8-bc72-5a055ef68232.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWD1Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78147809-8498-4892-b108-f5d2edaef0be

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 3'UTR 2, Intron 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 551/668 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- UMOD | c.1803G>T p.L601F | Missense Mutation (SNP) | VAF 34/756 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1181331307, COSV56775308; called by muse, mutect2
- BARX2 | c.676A>G p.S226G | Missense Mutation (SNP) | VAF 506/956 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- MCM9 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 90/656 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- REXO1 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SPINT2 | c.592+1G>A p.X198_splice | Splice Site (SNP) | VAF 76/639 reads (12%) | called by muse, mutect2, varscan2
- ZNF16 | c.350A>T p.D117V | Missense Mutation (SNP) | VAF 64/1025 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.11); called by muse, mutect2
- ADGRB2 | c.966C>T p.S322= | Silent (SNP) | VAF 168/471 reads (36%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.87C>T p.A29= | Silent (SNP) | VAF 92/363 reads (25%) | catalogued as rs1342142038; called by muse, mutect2, varscan2
- SEZ6L2 | c.1188G>A p.S396= (on ENST00000308713 / NM_001114099.3; = p.S326= on NM_012410.4) | Silent (SNP) | VAF 59/467 reads (13%) | catalogued as rs1228536537, COSV58098591; called by muse, mutect2, varscan2
- SLC24A4 | c.954G>A p.K318= | Silent (SNP) | VAF 28/892 reads (3%) | called by muse, mutect2
- BCL11B | c.-100_-99insAGCGGC | 5'UTR (INS) | VAF 5/68 reads (7%) | catalogued as rs1195993811; called by mutect2, pindel
- LARS2 | c.*795-11C>T | Intron (SNP) | VAF 57/304 reads (19%) | catalogued as rs112692322; called by muse, mutect2, varscan2
- RPL39L | c.*69C>A | 3'UTR (SNP) | VAF 54/314 reads (17%) | called by muse, mutect2, varscan2
- TRIM61 | c.526-2306C>A | Intron (SNP) | VAF 95/572 reads (17%) | called by muse, mutect2, varscan2
- VANGL1 | c.*72G>A | 3'UTR (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
